EXCEPTIONAL_RESPONDERS case ER-ABOM — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5e00951-ad65-414f-80d5-f363bfa83c25

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Dead; Days to death: 1,923 days (5.3 years); Year of death: 2018.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 67.8 years (24,753 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic stage: Stage IA; Prior malignancy: no; Days to last follow up: 771 days (2.1 years); Days to best overall response: 651 days (1.8 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Zoledronic Acid; Days to treatment start: 424 days (1.2 years).
   Treatment given: Therapeutic agents: Afatinib; Days to treatment start: 435 days (1.2 years).

Follow-up (1 entry)
- Days to follow up: 771 days (2.1 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 771 days (2.1 years); Days to recurrence: 396 days (1.1 years); Days progression-free: 651 days (1.8 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABOM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABOM-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 33; Percent tumor nuclei: 5; Percent normal cells: 67; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
